Gene-level copy-number profile of tumor specimen C3L-07213-01 from CPTAC case C3L-07213, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 28.1 years (10,254 days).
Specimen C3L-07213-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 12781ebb-e8c7-46a5-9695-aeb69dd96372.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07213-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/8d735b32-55aa-40e3-b6b0-3c8e7b7aaf3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,248; copy number 2: 54,893; copy number 3: 1,258; copy number 4: 5; copy number 5: 1; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,290,071–12,318,316, 2 genes, copy number 5–6: DEFB131D, DEFB130A.

Autosomal genes at a single copy (total copy number 1): 1,750. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
